Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CM, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CM-01A (Primary Tumor).

[page 1 of 2]
10/15/11

History Case Pathology Report

DOB: _____
Physician: _____

Sex: F

Received: _____

Pathologist: _____

Accession: _____

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to _____, the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

FINAL DATE

TO:

CLINIC COPY TO:

SUPPLEMENTAL REPORT

DIAGNOSIS :

- (A) ANTERIOR WALL THYROID AND TRACHEAL CARTILAGE:
PAPILLARY CARCINOMA OF THYROID FOCALLY INVOLVING INFERIOR
TRACHEAL MARGIN OF RESECTION. (SEE COMMENT)

COMMENT: The remaining surgical margins of resection are negative for tumor.

ICD-0-3
Carcinoma, Papillary, thyroid
Site: thyroid C73.9 8260/3
hw 10/15/11

DIAGNOSIS

- (A) ANTERIOR WALL THYROID AND TRACHEAL CARTILAGE:
Pending decalcification, addendum to follow.
- (B) BILATERAL NECK DISSECTION, TOTAL THYROIDECTOMY AND MEDIASTINAL NODE DISSECTION:
PAPILLARY CARCINOMA OF THE THYROID, 5.0 CM MAXIMUM DIMENSION, EXTENDING INTO THE ADJACENT SOFT TISSUE AND EXTENDING TO THE DEEP MARGIN OF RESECTION. (SEE COMMENT)
METASTATIC PAPILLARY CARCINOMA IN 1 OF 8 LYMPH NODES IN THE LEFT NECK DISSECTION (AREA 3, 0/1; AREA 4, 0/1; AREA 5, 1/1; AREA 6, NO LYMPH NODES; AREA 7, 0/2; AREA 8, 0/3).
METASTATIC PAPILLARY CARCINOMA IN 2 OF 8 LYMPH NODES IN THE RIGHT NECK DISSECTION (AREA 3, 1/3; AREA 4, NO LYMPH NODES; AREA 5, 0/2; AREA 6, NO LYMPH NODES; AREA 7, 1/3).

COMMENT

The papillary carcinoma appears well differentiated and shows only focal necrosis. Tumor involves almost entirely the left lobe and the isthmus and portion of the right lobe of thyroid. Furthermore it extends into the surrounding soft tissue and extends to the deep margin of resection. The largest involved lymph node is present on the right side in area 7 and measures 2.5 cm in maximum dimension with the tumor totally effacing it. There is extracapsular extension measuring 0.3 mm in maximum dimension in the largest lymph node involved.

SPECIMEN

- (A) ANTERIOR WALL THYROID AND TRACHEAL CARTILAGE:
(B) BILATERAL NECK DISSECTION, TOTAL THYROIDECTOMY AND MEDIASTINAL NODE

[page 2 of 2]
History Case Pathology Report

DOB:
Physician:

Sex: F

Received: ..

Pathologist: ..

Case type: Surgical History

Accession: ..

SNOMED CODES

Source: NCI Genomic Data Commons file d5b53659-090d-42f0-8d35-3f76038cfa1b (TCGA-EL-A3CM.FE838902-B02D-4EA3-A810-4486F7FE8F0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).